Gene-level copy-number profile of specimen HCM-BROD-0115-C16-85A from HCMI case HCM-BROD-0115-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 43.5 years (15,886 days).
Specimen HCM-BROD-0115-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3124256f-5439-4463-ab4d-b90996ff6946.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0115-C16-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/a13bf3d9-99d3-4c1a-b277-863d4b49671b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 618; copy number 1: 8,701; copy number 2: 38,647; copy number 3: 10,316; copy number 4: 594; copy number 5: 16; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 106 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:987,180–1,006,623, 2 genes: AC116351.1, AC116351.2.
- chr9:14,081,843–14,910,995, 14 genes: NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P.
- chr9:14,921,337–15,019,729, 2 genes (within-gene range 0–1): LDHAP4, AL592293.1.
- chr9:21,453,802–30,935,977, 88 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:140,865,075–141,456,434, 13 genes, copy number 5: AC121333.1, RPL23AP41, SLC25A36, AC108727.1, SPSB4, AC108727.2, PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2, ZBTB38, AC010184.1.
- chr5:70,219,918–70,258,930, 1 gene, copy number 5: GUSBP14.
- chr9:64,637,845–64,709,311, 2 genes, copy number 9: AL445665.1, BMS1P11.
- chr21:10,122,273–10,129,029, 1 gene, copy number 5: CR382287.1.
- chr21:13,792,635–13,793,141, 1 gene, copy number 5: FAM207CP.

Autosomal genes at a single copy (total copy number 1): 6,357. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
